Somatic mutation profile of tumor specimen 0DXAQY from CCDI case PBCPWW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 13.6 years (4,961 days).
Specimen 0DXAQY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e5f04146-f094-498b-9e00-25cd5e6a1441.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DXAQE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b501110-df8d-4ca9-91ff-a94f56daf6ce

The open-access MAF lists 85 somatic variants for this specimen: 62 protein-altering or splice-affecting, 8 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Intron 8, Silent 8, Nonsense Mutation 7, 3'UTR 5, Splice Site 4, 5'UTR 2, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.1004A>T p.K335I | Missense Mutation (SNP) | VAF 12/386 reads (3%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV62688046, COSV62689047, COSV62695316; called by muse, mutect2
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 18/347 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2
- FBXW7 | c.1100G>C p.R367P (on ENST00000281708 / NM_001349798.2; = p.R287P on NM_018315.5) | Missense Mutation (SNP) | VAF 51/329 reads (16%) | hotspot (GDC flag); SIFT tolerated (0.1); PolyPhen benign (0.294); catalogued as COSV55945291; called by muse, mutect2, varscan2
- MET | c.3749T>C p.M1250T | Missense Mutation (SNP) | VAF 117/596 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913245, CM992181, COSV59255872; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC9 | c.3290C>A p.S1097* | Nonsense Mutation (SNP) | VAF 26/456 reads (6%) | catalogued as COSV53983620; called by muse, mutect2
- ADPRHL1 | c.3866C>T p.S1289L | Missense Mutation (SNP) | VAF 24/279 reads (9%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.514); catalogued as rs932643353; called by muse, mutect2
- ATM | c.1760G>A p.G587D | Missense Mutation (SNP) | VAF 16/432 reads (4%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs1060501553, COSV53731743; ClinVar: uncertain significance; called by muse, mutect2
- CBFA2T2 | c.720-1G>A p.X240_splice | Splice Site (SNP) | VAF 19/506 reads (4%) | catalogued as COSV60073485; called by muse, mutect2
- CERK | c.1361G>A p.R454H | Missense Mutation (SNP) | VAF 31/440 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs771578079, COSV53450036; called by muse, mutect2
- FAM126A | c.88A>C p.N30H | Missense Mutation (SNP) | VAF 16/608 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as COSV69016801; called by muse, mutect2
- H2BC9 | c.205G>C p.D69H | Missense Mutation (SNP) | VAF 27/396 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.597); catalogued as COSV55099863, COSV55100002; called by muse, mutect2
- IRAK3 | c.618G>T p.W206C | Missense Mutation (SNP) | VAF 20/356 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV54162454; called by muse, mutect2
- MAML3 | c.618G>T p.L206F | Missense Mutation (SNP) | VAF 40/486 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.844); catalogued as rs1321346324; called by muse, mutect2
- MET | c.1235G>A p.R412H | Missense Mutation (SNP) | VAF 113/557 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.017); catalogued as rs371463233, COSV99041926; called by muse, mutect2, varscan2
- OR10J1 | c.417G>C p.R139S | Missense Mutation (SNP) | VAF 17/337 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as rs1220198900; called by muse, mutect2
- OR1F1 | c.331G>T p.D111Y | Missense Mutation (SNP) | VAF 26/239 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV58960952; called by muse, mutect2, varscan2
- PROX1 | c.709C>G p.R237G | Missense Mutation (SNP) | VAF 58/614 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.812); catalogued as COSV54780655; called by muse, mutect2
- RAP1GAP2 | c.675+2T>C p.X225_splice | Splice Site (SNP) | VAF 33/643 reads (5%) | catalogued as COSV54579350; called by muse, mutect2
- RBM10 | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 49/235 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV61311152; called by muse, mutect2, varscan2
- SHISA9 | c.1051C>A p.R351S | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as COSV69644859; called by muse, mutect2
- SPSB1 | c.538G>T p.A180S | Missense Mutation (SNP) | VAF 30/614 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.17); catalogued as COSV60164629; called by muse, mutect2
- TCTEX1D1 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 24/260 reads (9%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs376669297; called by muse, mutect2
- TSC2 | c.3233G>A p.R1078Q | Missense Mutation (SNP) | VAF 34/532 reads (6%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.945); catalogued as rs368095502; ClinVar: benign; called by muse, mutect2
- ZNF443 | c.1225C>G p.R409G | Missense Mutation (SNP) | VAF 15/214 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV56893439; called by muse, mutect2
- ZNF503 | c.1456G>A p.A486T | Missense Mutation (SNP) | VAF 18/342 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.073); catalogued as rs1471936316; called by muse, mutect2
- ZNF625 | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 18/260 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs749950854; called by muse, mutect2
- AL031777.2 | c.313C>T p.Q105* | Nonsense Mutation (SNP) | VAF 22/457 reads (5%) | called by muse, mutect2
- ANO5 | c.1276C>A p.L426M | Missense Mutation (SNP) | VAF 18/492 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); called by muse, mutect2
- BBS4 | c.326G>T p.R109I | Missense Mutation (SNP) | VAF 62/414 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BMP3 | c.148C>A p.L50M | Missense Mutation (SNP) | VAF 20/294 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); called by muse, mutect2
- BRINP1 | c.1273C>T p.P425S | Missense Mutation (SNP) | VAF 10/332 reads (3%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.992); called by muse, mutect2
- CANT1 | c.112dup p.R38Pfs*52 | Frame Shift Ins (INS) | VAF 26/232 reads (11%) | called by mutect2, pindel, varscan2
- CDH24 | c.1647T>G p.S549R | Missense Mutation (SNP) | VAF 54/310 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.051); called by muse, mutect2
- CLCA1 | c.1244A>T p.D415V | Missense Mutation (SNP) | VAF 92/512 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLIP4 | c.885+1G>T p.X295_splice | Splice Site (SNP) | VAF 26/365 reads (7%) | called by muse, mutect2
- DDX17 | c.403T>C p.Y135H | Missense Mutation (SNP) | VAF 14/478 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- DLGAP1 | c.1114C>T p.R372W | Missense Mutation (SNP) | VAF 20/493 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DMGDH | c.1901G>T p.G634V | Missense Mutation (SNP) | VAF 24/466 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EN1 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 30/311 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- G6PC | c.226A>T p.K76* | Nonsense Mutation (SNP) | VAF 21/362 reads (6%) | called by muse, mutect2
- HIP1 | c.479C>A p.P160Q | Missense Mutation (SNP) | VAF 17/490 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- KASH5 | c.1298C>A p.P433H | Missense Mutation (SNP) | VAF 55/522 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRCH3 | c.2041G>A p.A681T | Missense Mutation (SNP) | VAF 83/403 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MTMR14 | c.418C>G p.H140D | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.243); called by muse, mutect2
- MYO1G | c.738C>A p.D246E | Missense Mutation (SNP) | VAF 28/846 reads (3%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2
- NBEAL2 | c.6605G>A p.W2202* | Nonsense Mutation (SNP) | VAF 28/712 reads (4%) | called by muse, mutect2
- OLR1 | c.424+1G>T p.X142_splice | Splice Site (SNP) | VAF 21/225 reads (9%) | called by muse, mutect2
- OR10A6 | c.703C>G p.Q235E | Missense Mutation (SNP) | VAF 54/811 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); called by muse, mutect2
- OR5T3 | c.43C>A p.L15M | Missense Mutation (SNP) | VAF 24/400 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- PCLO | c.2359G>C p.A787P | Missense Mutation (SNP) | VAF 89/586 reads (15%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PEG10 | c.65A>G p.K22R (on ENST00000482108 / NM_001040152.2; = p.K56R on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/476 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- PIEZO2 | c.5512G>T p.E1838* | Nonsense Mutation (SNP) | VAF 38/389 reads (10%) | called by muse, mutect2, varscan2
- RANBP2 | c.1009G>T p.E337* | Nonsense Mutation (SNP) | VAF 24/745 reads (3%) | called by muse, mutect2
- RGS22 | c.927C>A p.F309L | Missense Mutation (SNP) | VAF 25/501 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.184); called by muse, mutect2
- SERINC3 | c.1054A>G p.S352G | Missense Mutation (SNP) | VAF 27/385 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); called by muse, mutect2
- SIN3A | c.3077C>A p.A1026E | Missense Mutation (SNP) | VAF 16/332 reads (5%) | SIFT tolerated (0.66); PolyPhen benign (0.003); called by muse, mutect2
- SLC26A1 | c.65C>A p.P22Q | Missense Mutation (SNP) | VAF 50/458 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.06); called by muse, mutect2
- SLC35A2 | c.268A>T p.K90* | Nonsense Mutation (SNP) | VAF 81/379 reads (21%) | called by muse, mutect2, varscan2
- SPEN | c.9034del p.T3012Lfs*10 | Frame Shift Del (DEL) | VAF 56/533 reads (11%) | called by mutect2, pindel, varscan2
- ZBBX | c.1088G>T p.S363I | Missense Mutation (SNP) | VAF 12/299 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.081); called by muse, mutect2
- ZFHX4 | c.3685C>A p.Q1229K | Missense Mutation (SNP) | VAF 21/470 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
- ZNF84 | c.1305G>T p.Q435H | Missense Mutation (SNP) | VAF 44/491 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.765); called by muse, mutect2
- CES2 | c.651C>A p.G217= | Silent (SNP) | VAF 30/310 reads (10%) | called by muse, mutect2, varscan2
- CUL9 | c.378G>A p.A126= | Silent (SNP) | VAF 36/462 reads (8%) | catalogued as rs374118842; called by muse, mutect2
- GPANK1 | c.513G>A p.G171= | Silent (SNP) | VAF 22/338 reads (7%) | catalogued as rs753558725, COSV63263567; called by muse, mutect2
- LGR5 | c.1866C>A p.G622= | Silent (SNP) | VAF 32/462 reads (7%) | called by muse, mutect2
- MUC12 | c.552T>C p.S184= (on ENST00000379442; = p.S41= on NM_001164462.1) | Silent (SNP) | VAF 32/733 reads (4%) | called by muse, mutect2
- PLEC | c.5491C>T p.L1831= (on ENST00000322810 / NM_201380.4; = p.L1721= on NM_000445.5) | Silent (SNP) | VAF 37/351 reads (11%) | catalogued as rs1373326735; ClinVar: likely benign; called by muse, mutect2, varscan2
- RPS6KC1 | c.1704C>T p.H568= | Silent (SNP) | VAF 50/579 reads (9%) | catalogued as rs754360220, COSV65297011; called by muse, mutect2
- TRRAP | c.2766C>A p.P922= | Silent (SNP) | VAF 59/726 reads (8%) | called by muse, mutect2
- ARMC6 | c.1293+34G>A | Intron (SNP) | VAF 17/210 reads (8%) | called by muse, mutect2
- CLEC1A | c.-15G>T | 5'UTR (SNP) | VAF 35/336 reads (10%) | called by muse, mutect2, varscan2
- CSMD1 | c.6034+59G>T | Intron (SNP) | VAF 20/165 reads (12%) | called by muse, mutect2, varscan2
- EPPIN | c.*19G>T | 3'UTR (SNP) | VAF 28/458 reads (6%) | called by muse, mutect2
- FAM166A | c.272-15G>T | Intron (SNP) | VAF 49/460 reads (11%) | called by muse, mutect2, varscan2
- IFNAR2 | c.841-38T>A | Intron (SNP) | VAF 36/234 reads (15%) | called by muse, mutect2, varscan2
- PML | c.1710+881C>T | Intron (SNP) | VAF 37/349 reads (11%) | catalogued as rs150442989; called by muse, mutect2, varscan2
- PPFIBP1 | c.*34G>T | 3'UTR (SNP) | VAF 23/153 reads (15%) | called by muse, mutect2, varscan2
- RABGEF1 | c.-66A>G | 5'UTR (SNP) | VAF 10/188 reads (5%) | called by muse, mutect2
- SFMBT1 | c.*82A>C | 3'UTR (SNP) | VAF 12/156 reads (8%) | called by muse, mutect2
- SLC30A2 | c.271+590C>T | Intron (SNP) | VAF 38/709 reads (5%) | catalogued as rs765207533, CM158605; called by muse, mutect2
- SLC35A2 | c.*42C>G | 3'UTR (SNP) | VAF 28/322 reads (9%) | catalogued as COSV99504653; called by muse, mutect2
- SLC39A13 | c.786+21C>T | Intron (SNP) | VAF 17/363 reads (5%) | called by muse, mutect2
- SPTBN4 | c.7536+14C>T | Intron (SNP) | VAF 12/307 reads (4%) | catalogued as rs1437231157; called by muse, mutect2
- ZNF146 | c.*34T>C | 3'UTR (SNP) | VAF 16/118 reads (14%) | catalogued as rs202080948; called by muse, mutect2, varscan2
